Gene-level copy-number profile of tumor specimen MP2PRT-PAUZZP-TMP1-A from MP2PRT case MP2PRT-PAUZZP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,365 days).
Specimen MP2PRT-PAUZZP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7800e1f1-bd2a-4d6b-82ef-c81387e80f8f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUZZP-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/78dba05f-d50d-4cd6-9a06-1cd97d339b57

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 620; copy number 1: 1,537; copy number 2: 54,813; copy number 3: 1,396; copy number 4: 25.

Homozygous deletions (total copy number 0; autosomes only): 620 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–686,673, 41 genes (within-gene range 0–1): DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AC114498.1, MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, OR4F16.
- chr1:248,601,416–248,937,043, 19 genes: AC098483.2, OR2T11, OR2T35, OR2T27, CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P, RPL23AP25.
- chr2:38,814–46,870, 1 gene: FAM110C.
- chr2:88,857,161–89,245,596, 37 genes (within-gene range 0–2): IGKC, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr2:241,881,363–242,175,634, 12 genes: LINC01237, FAM240C, LINC01238, AC093642.3, AC093642.1, AC093642.6, LINC01880, AC093642.2, LINC01881, CICP10, SEPTIN14P2, RPL23AP88.
- chr3:11,745–54,346, 2 genes: LINC01986, AC066595.1.
- chr4:49,096–88,208, 2 genes: BNIP3P41, ZNF595.
- chr5:58,198–438,291, 16 genes (within-gene range 0–1): AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2.
- chr6:105,919–206,392, 6 genes: OR4F1P, CICP18, AL035696.2, AL035696.3, AL035696.4, AL035696.1.
- chr7:38,257,879–38,329,643, 10 genes (within-gene range 0–1): TRGC1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2.
- chr7:159,231,435–159,233,377, 1 gene: PIP5K1P2.
- chr8:64,091–477,967, 17 genes: AC144568.1, AC144568.2, AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1.
- chr8:144,876,497–145,066,685, 9 genes: ZNF250, ZNF16, ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr9:12,134–465,259, 14 genes (within-gene range 0–1): DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, DOCK8-AS1, DOCK8, AL158832.1.
- chr10:14,061–254,637, 7 genes: AC215217.1, AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297.
- chr10:133,394,094–133,778,699, 31 genes (within-gene range 0–1): MTG1, SPRN, OR6L2P, SCART1, OR7M1P, CYP2E1, AL161645.1, AL161645.2, SYCE1, AL731769.2, OR6L1P, FRG2B, RARRES2P2, AGGF1P2, CLUHP5, DUX4L28, DUX4L25, DUX4L24, DUX4L23, DUX4L22, DUX4L21, DUX4L20, DUX4L29, DUX4L10, DUX4L11, DUX4L12, DUX4L13, DUX4L14, DUX4L15, RPL23AP60, BX322534.1.
- chr11:134,985,683–135,075,908, 2 genes: AP003062.1, LINC02684.
- chr12:12,310–586,486, 18 genes (within-gene range 0–1): DDX11L8, WASH8P, FAM138D, IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, AC006205.2.
- chr12:132,972,338–133,238,549, 19 genes: NANOGNBP2, ZNF26, RNU4ATAC12P, ZNF84-DT, PTP4A1P2, ZNF84, AC073911.1, AC073911.2, ZNF140, ZNF891, AC026786.2, RPL23AP67, ZNF10, AC026786.1, ZNF268, AC226150.1, ANHX, RNU6-717P, Y_RNA.
- chr13:114,234,887–114,337,626, 7 genes: CDC16, MIR548AR, MIR4502, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr14:22,438,547–22,490,553, 23 genes (within-gene range 0–2): TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48.
- chr14:105,672,308–106,879,812, 186 genes (within-gene range 0–2) (broad region; genes not listed).
- chr15:101,621,444–101,979,093, 23 genes: TM2D3, RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.
- chr16:11,555–352,723, 31 genes: DDX11L10, WASH4P, MIR6859-4, Z84723.1, WASIR2, IL9RP3, POLR3K, SNRNP25, RHBDF1, Z69720.2, MPG, NPRL3, Z69720.1, Z69666.1, HBZ, HBM, HBZP1, HBAP1, HBA2, HBA1, Y_RNA, HBQ1, Z69706.1, LUC7L, Z69890.1, FAM234A, RGS11, Z69667.1, ARHGDIG, PDIA2, AXIN1.
- chr16:90,056,566–90,222,851, 8 genes: PRDM7, TUBB8P7, FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:83,098,377–83,240,804, 6 genes: AC130371.2, AC144831.1, AC139099.3, AC139099.2, AC139099.1, RPL23AP87.
- chr18:45,034–214,629, 8 genes (within-gene range 0–1): AP001005.1, TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14.
- chr18:80,034,346–80,247,514, 9 genes: AC090360.1, RBFA, RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.
- chr19:58,367,618–58,605,223, 31 genes: ZNF837, RPS5, MIR4754, RNF225, LINC02560, ZNF584, AC012313.1, AC012313.4, AC012313.5, ZNF132, AC012313.8, ZNF324B, ZNF324, ZNF446, AC012313.7, SLC27A5, RNU6-1337P, RN7SL693P, AC012313.9, ZBTB45, RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1, AC016629.2.
- chr20:87,250–268,857, 7 genes: DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1.
- chr20:64,255,695–64,327,972, 5 genes: PCMTD2, AL137028.2, CICP4, LINC00266-1, AL137028.1.
- chr21:46,690,764–46,691,226, 1 gene: RPL23AP4.
- chr22:50,669,804–50,801,309, 9 genes: Y_RNA, SHANK3, RNU6-409P, AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,519. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
